Somatic mutation profile of tumor specimen TCGA-VQ-A91X-01A (aliquot TCGA-VQ-A91X-01A-12D-A410-08) from TCGA case TCGA-VQ-A91X, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 74.8 years (27,314 days).
Specimen TCGA-VQ-A91X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 255af841-5239-41b8-987e-cd9d5b25e372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A91X-10A (Blood Derived Normal), aliquot TCGA-VQ-A91X-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d14050e-3007-45d1-87ff-78f03a4c5c04

The open-access MAF lists 230 somatic variants for this specimen: 181 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 43, Nonsense Mutation 8, Frame Shift Ins 7, Frame Shift Del 4, Splice Site 4, Intron 2, 3'UTR 1, 5'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2B | c.521dup p.T176Dfs*8 | Frame Shift Ins (INS) | VAF 21/121 reads (17%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, varscan2
- MYO15A | c.3311dup p.E1105* | Frame Shift Ins (INS) | VAF 10/64 reads (16%) | catalogued as rs794729637; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.1473T>G p.I491M | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as COSV99190995; called by muse, mutect2, varscan2
- ABCA13 | c.13462T>G p.L4488V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101291386; called by muse, mutect2, varscan2
- AC005324.2 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.59); catalogued as COSV100371998, COSV60888016; called by muse, mutect2, varscan2
- ADAMTS5 | c.476A>C p.K159T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV99538019; called by muse, mutect2, varscan2
- ADCY10 | c.1787T>A p.L596H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100896975; called by muse, mutect2, varscan2
- ALOX15B | c.1861G>C p.G621R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205652; called by muse, mutect2, varscan2
- ANK2 | c.1742T>G p.L581R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52178943; called by muse, mutect2, varscan2
- ANO5 | c.978T>G p.I326M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV100202031; called by muse, mutect2, varscan2
- ANO9 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs372316223; called by muse, mutect2, varscan2
- ATAD2 | c.631A>C p.T211P | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99785012; called by muse, mutect2, varscan2
- ATP10A | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1466802755, COSV100791393; called by muse, mutect2, varscan2
- BICRA | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as COSV101194401; called by muse, mutect2, varscan2
- C9orf78 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs754038817, COSV100693966; called by muse, mutect2
- CACHD1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200240221, COSV51547290; called by muse, mutect2, varscan2
- CAP2 | c.1356A>C p.E452D | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100012704; called by muse, mutect2, varscan2
- CCR5 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs55916127, COSV99433551; called by muse, mutect2, varscan2
- CD300C | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs752276696, COSV100423290; called by mutect2, varscan2
- CD300LG | c.453A>T p.K151N | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as COSV99517535; called by muse, mutect2
- CD69 | c.380A>G p.K127R | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.673); catalogued as COSV99946146; called by muse, mutect2, varscan2
- CDKAL1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 61/124 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV99215997; called by muse, mutect2, varscan2
- CHIA | c.487C>T p.R163C (on ENST00000343320; = p.R55C on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as rs139158262, COSV100588563; called by mutect2, varscan2
- CHRND | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs142928493; called by muse, mutect2, varscan2
- CMYA5 | c.5952A>T p.E1984D | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV101483776, COSV101484204; called by muse, mutect2, varscan2
- CNTNAP4 | c.3346T>G p.F1116V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as COSV100272368; called by muse, mutect2, varscan2
- COL6A6 | c.772G>T p.A258S | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.068); catalogued as COSV100650598; called by muse, mutect2, varscan2
- CST9 | c.35G>A p.W12* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100980489; called by muse, mutect2, varscan2
- CYP4F11 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs142657300; called by muse, mutect2, varscan2
- CYP4F2 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as rs140630977; called by muse, mutect2, varscan2
- DCAF6 | c.479G>C p.C160S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100394528; called by muse, mutect2, varscan2
- DDIAS | c.2267C>G p.S756* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100231318; called by muse, mutect2, varscan2
- DEAF1 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773963410, COSV100102194; called by muse, mutect2, varscan2
- DHCR24 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs201146876, COSV100987828; called by muse, mutect2, varscan2
- DMXL1 | c.4684G>A p.A1562T | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.816); catalogued as rs1212118079, COSV100224458; called by muse, mutect2
- DNAH5 | c.3726A>T p.K1242N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV99451865; called by muse, mutect2, varscan2
- DNAH8 | c.13004C>T p.T4335M | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs375993164; called by muse, mutect2, varscan2
- DSCAM | c.2036A>G p.E679G | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV68028099, COSV68031740; called by muse, mutect2, varscan2
- DSG4 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1244455121, COSV57389442; called by muse, mutect2, varscan2
- DST | c.19229C>T p.P6410L (on ENST00000361203 / NM_001374722.1; = p.P4107L on NM_015548.5) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs776871988, COSV55014438; called by muse, mutect2, varscan2
- EDEM2 | c.1532G>C p.S511T | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1311686322, COSV100788025; called by muse, mutect2
- EDRF1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as COSV100523728; called by muse, mutect2
- EFHC1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV64135410; called by muse, mutect2, varscan2
- ELFN2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs568588590, COSV101297595; called by muse, mutect2, varscan2
- ELMO1 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 57/359 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV100165179, COSV60308092, COSV60319704; called by muse, varscan2
- ELMOD2 | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100063013; called by muse, mutect2, varscan2
- EOLA2 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 52/68 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV100778087; called by muse, mutect2, varscan2
- EPHA5 | c.2965A>C p.N989H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99900067; called by muse, mutect2, varscan2
- EPHA7 | c.1802A>C p.K601T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as COSV65177734; called by muse, mutect2, varscan2
- ERCC6L2 | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV99998849; called by muse, mutect2
- FAM117A | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs781423934, COSV99544981; called by muse, mutect2
- FAM124A | c.851A>C p.K284T (on ENST00000322475 / NM_001242312.2; = p.K320T on NM_145019.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.382); catalogued as COSV99696401; called by muse, mutect2, varscan2
- FAM171A1 | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as rs758289605, COSV100968213, COSV65313453; called by muse, mutect2, varscan2
- FAT2 | c.2399A>G p.K800R | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.582); catalogued as COSV99943618; called by muse, mutect2, varscan2
- FGF10 | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99240801; called by muse, mutect2, varscan2
- FGF13 | c.215A>C p.K72T | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs912731987, COSV100264440; called by muse, mutect2, varscan2
- FILIP1 | c.2490A>T p.E830D | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV99385480; called by muse, mutect2, varscan2
- FLI1 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99857922; called by muse, mutect2, varscan2
- FLRT2 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100420725, COSV58149961; called by muse, mutect2, varscan2
- FSIP2 | c.16799T>C p.L5600P | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100555699; called by muse, mutect2, varscan2
- GIMAP6 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1203420903, COSV100188325; called by muse, mutect2, varscan2
- GLRA3 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs201620617; called by muse, mutect2, varscan2
- GNPTAB | c.977A>C p.N326T | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV100172195; called by muse, mutect2, varscan2
- GRID2 | c.1955T>G p.L652R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56190673, COSV99943763; called by muse, mutect2, varscan2
- GRM1 | c.1691C>A p.A564D | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99267603; called by muse, mutect2, varscan2
- HFM1 | c.2087T>G p.L696R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99646355; called by muse, mutect2, varscan2
- HMCN1 | c.9944G>A p.G3315E | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99632404; called by muse, mutect2, varscan2
- IMPG1 | c.1802T>C p.L601P | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100886517; called by muse, mutect2, varscan2
- IMPG2 | c.1600A>C p.S534R | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV51986244, COSV99514564; called by muse, mutect2, varscan2
- IRF2BP1 | c.913G>T p.G305C | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100138951; called by muse, mutect2, varscan2
- KCNH3 | c.383T>C p.V128A | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.241); catalogued as COSV99235517; called by muse, mutect2, varscan2
- KCNK18 | c.641T>G p.L214R | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100572078; called by muse, mutect2
- KIAA1549L | c.4226G>A p.R1409H (on ENST00000321505; = p.R1706H on NM_012194.3) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs565978185, COSV58585296; called by muse, mutect2, varscan2
- KRT72 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs775526937, COSV53373840, COSV53377831; called by muse, mutect2, varscan2
- KRT79 | c.1331C>G p.A444G | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100398493; called by muse, mutect2, varscan2
- KRT82 | c.1247A>T p.E416V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233758; called by muse, mutect2, varscan2
- LAMA1 | c.1488C>A p.N496K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs781121049, COSV67533529, COSV67540434; called by muse, mutect2, varscan2
- LRP1B | c.12835T>G p.F4279V | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101258249; called by muse, mutect2, varscan2
- LRP1B | c.1438T>C p.Y480H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV101258253; called by muse, mutect2, varscan2
- MAGEB3 | c.104A>C p.K35T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV100854749, COSV64397424, COSV64397481; called by muse, mutect2, varscan2
- MAGI3 | c.3236T>C p.I1079T | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100289774; called by muse, mutect2, varscan2
- MAP2 | c.4371A>C p.E1457D | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV52286196; called by muse, mutect2, varscan2
- MAP2K4 | c.818A>G p.E273G | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62261002; called by muse, mutect2, varscan2
- MASP1 | c.744+1G>T p.X248_splice | Splice Site (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99397431; called by muse, mutect2, varscan2
- MDH2 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 15/117 reads (13%) | catalogued as COSV100242755; called by muse, mutect2, varscan2
- MDM4 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100914570; called by muse, mutect2
- MED13L | c.4811C>T p.S1604F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.372); catalogued as rs138117728, COSV56132808; called by muse, mutect2, varscan2
- MKKS | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100726301; called by muse, mutect2, varscan2
- MLIP | c.1318-1G>T p.X440_splice | Splice Site (SNP) | VAF 12/72 reads (17%) | catalogued as COSV99229902; called by muse, mutect2, varscan2
- MMP13 | c.1290A>C p.K430N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99506719; called by muse, mutect2, varscan2
- MPDZ | c.5215A>C p.S1739R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1374913018, COSV100057204; called by muse, mutect2, varscan2
- MRGPRX2 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100316792; called by muse, mutect2, varscan2
- MYO7A | c.3213G>T p.M1071I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as rs374428473, COSV68686529; called by muse, mutect2, varscan2
- MYPN | c.3491T>C p.V1164A | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.45); catalogued as rs1334143316, COSV100590298; called by muse, mutect2, varscan2
- MYT1 | c.2989+2T>A p.X997_splice | Splice Site (SNP) | VAF 4/62 reads (6%) | catalogued as COSV100115080; called by muse, mutect2
- NAA50 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763096981, COSV99568742; called by muse, mutect2, varscan2
- NCKAP5 | c.2377G>T p.G793C | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100493390; called by muse, mutect2, varscan2
- NDST4 | c.1798A>C p.I600L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as COSV99997153; called by muse, mutect2
- NEB | c.11163T>G p.N3721K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99425560; called by muse, mutect2, varscan2
- NEB | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV51473529; called by muse, mutect2, varscan2
- NEK10 | c.2524A>C p.S842R | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV55364161; called by muse, mutect2, varscan2
- NEUROD4 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV99669989; called by muse, mutect2, varscan2
- NPBWR1 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.805); catalogued as rs1468157841, COSV58696214; called by muse, mutect2, varscan2
- NR0B1 | c.1408A>C p.I470L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100973556; called by muse, mutect2, varscan2
- NUP210 | c.4909G>T p.A1637S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99595532, COSV99596593; called by muse, mutect2, varscan2
- OBI1 | c.1641G>T p.E547D | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV99932562; called by muse, mutect2, varscan2
- OR10A4 | c.324T>G p.F108L | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.965); catalogued as rs1354907152, COSV65842554; called by muse, mutect2, varscan2
- OR2M2 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 44/297 reads (15%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as COSV100677274; called by muse, mutect2, varscan2
- OR4X2 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583339, COSV56583711; called by muse, mutect2, varscan2
- OR52H1 | c.454T>C p.F152L (on ENST00000322653; = p.F158L on NM_001005289.1) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs920111736, COSV100497345; called by muse, mutect2, varscan2
- OR52J3 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1247837063, COSV66746307, COSV66746315; called by muse, mutect2
- OR52M1 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64171654; called by muse, mutect2, varscan2
- OR6N2 | c.188T>G p.V63G | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100210290; called by muse, mutect2, varscan2
- PCARE | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs1372842373, COSV100527722; called by muse, mutect2, varscan2
- PCLO | c.10469G>T p.R3490M | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100434782; called by muse, mutect2, varscan2
- PDZD2 | c.790T>G p.F264V | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV99225858; called by muse, mutect2, varscan2
- PHOSPHO2 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs751867437, COSV99776013; called by muse, mutect2, varscan2
- PKHD1 | c.6317T>C p.L2106P | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM100420, COSV100583833, COSV61897850; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 24/119 reads (20%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLCL1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 10/64 reads (16%) | catalogued as COSV101407205; called by muse, mutect2
- PLXDC2 | c.1042T>C p.W348R | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101023141; called by muse, mutect2
- POLK | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99606231; called by muse, mutect2, varscan2
- PSG4 | c.28A>T p.T10S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.187); catalogued as COSV99737466; called by muse, mutect2
- PSMF1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.363); catalogued as COSV55675514, COSV99850646; called by muse, mutect2
- RNF217 | c.1593dup p.Q532Tfs*16 | Frame Shift Ins (INS) | VAF 26/71 reads (37%) | catalogued as rs1413029182; called by mutect2, pindel, varscan2
- S100A7A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs139970748; called by muse, mutect2, varscan2
- SGCZ | c.775G>T p.G259* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV66055409; called by muse, mutect2, varscan2
- SLC22A23 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs199592727, COSV66677557; called by muse, mutect2, varscan2
- SLC22A25 | c.27A>C p.Q9H | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV60599307; called by muse, mutect2, varscan2
- SLC7A1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.344); catalogued as COSV101060243; called by muse, varscan2
- SNX29 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV101625451; called by muse, varscan2
- SPATA31D1 | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100782923; called by muse, mutect2, varscan2
- ST6GAL2 | c.361C>A p.Q121K | Missense Mutation (SNP) | VAF 21/167 reads (13%) | PolyPhen benign (0.001); catalogued as COSV100868136; called by muse, mutect2, varscan2
- STK4 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs770104834, COSV100860329; called by muse, mutect2, varscan2
- SYCP2L | c.2297A>T p.E766V | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99305518; called by muse, mutect2
- SYNE1 | c.7484A>G p.E2495G (on ENST00000367255 / NM_182961.4; = p.E2502G on NM_033071.3) | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs1055070356, COSV54966819, COSV99572322; called by muse, mutect2, varscan2
- SYNE2 | c.13438G>C p.G4480R | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV100648141; called by muse, mutect2, varscan2
- TAF1L | c.5310A>C p.E1770D | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.986); catalogued as COSV99645040; called by muse, mutect2, varscan2
- TAS2R1 | c.814G>T p.G272* | Nonsense Mutation (SNP) | VAF 20/122 reads (16%) | catalogued as COSV101225818; called by muse, mutect2, varscan2
- TBCCD1 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.065); catalogued as rs140309382; called by mutect2, varscan2
- TECTA | c.6389T>G p.L2130R | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV99880652; called by muse, mutect2, varscan2
- TENM2 | c.8239G>T p.V2747L (on ENST00000518659 / NM_001122679.2; = p.V2508L on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV101319135; called by muse, mutect2, varscan2
- TLR10 | c.820T>C p.F274L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100457804; called by muse, mutect2, varscan2
- TLR9 | c.686A>G p.Y229C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100564580; called by mutect2, varscan2
- TMEM35A | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as COSV99515519, COSV99515612; called by muse, mutect2, varscan2
- TOP1MT | c.796A>G p.N266D | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV100239561; called by muse, mutect2, varscan2
- TRHDE | c.1879A>C p.T627P | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV53867037; called by muse, mutect2, varscan2
- TRPM3 | c.3413T>G p.L1138R (on ENST00000357533 / NM_001366142.2; = p.L993R on NM_020952.6) | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100677923; called by muse, mutect2, varscan2
- TTLL13P | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100296628; called by muse, mutect2
- TTN | c.63173A>G p.Q21058R (on ENST00000591111; = p.Q13634R on NM_003319.4) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | PolyPhen benign (0.273); catalogued as COSV100621290; called by muse, mutect2, varscan2
- TTN | c.49971A>C p.K16657N (on ENST00000591111; = p.K9233N on NM_003319.4) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | PolyPhen probably damaging (0.923); catalogued as COSV100621296; called by muse, mutect2
- TTN | c.47968G>A p.V15990I (on ENST00000591111; = p.V8566I on NM_003319.4) | Missense Mutation (SNP) | VAF 49/121 reads (40%) | PolyPhen probably damaging (0.991); catalogued as rs749503285, COSV60285636; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.21073T>G p.L7025V (on ENST00000591111; = p.L6098V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen possibly damaging (0.828); catalogued as rs1243764269, COSV100621297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV99932582; called by muse, mutect2, varscan2
- UGT2B28 | c.623T>C p.M208T | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs373101039; called by muse, mutect2, varscan2
- UMODL1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV100210770; called by muse, mutect2, varscan2
- UNC5D | c.751+2T>G p.X251_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99777226; called by muse, mutect2, varscan2
- VANGL2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1187014622, COSV100925589; called by muse, mutect2, varscan2
- VWA5A | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as rs201440543; called by muse, mutect2, varscan2
- WASHC4 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.593); catalogued as COSV100162588; called by muse, mutect2, varscan2
- WASHC5 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100572953; called by muse, mutect2, varscan2
- XK | c.611A>C p.K204T | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV101064743; called by muse, mutect2, varscan2
- ZFHX4 | c.1550T>G p.F517C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.794); catalogued as rs200115998, COSV50480152; called by muse, mutect2, varscan2
- ZNF197 | c.2914A>G p.N972D | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.71); PolyPhen benign (0.078); catalogued as COSV99940118; called by muse, mutect2, varscan2
- ZNF205 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs142065853, COSV99530552; called by muse, mutect2, varscan2
- ZNF318 | c.3758C>A p.T1253N | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV100546371; called by muse, mutect2, varscan2
- ZNF407 | c.2447T>C p.L816P | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV99996230; called by muse, mutect2, varscan2
- ZNF454 | c.142A>G p.S48G | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs753420271, COSV100195160; called by muse, mutect2, varscan2
- ZNF99 | c.832A>C p.I278L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV101233898; called by muse, mutect2, varscan2
- CCL3L3 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CEP128 | c.3267dup p.E1090Rfs*11 | Frame Shift Ins (INS) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- EXT2 | c.442A>C p.N148H (on ENST00000343631; = p.N181H on NM_000401.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2
- IFNAR2 | c.755del p.L252* | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- KHDC1 | c.279dup p.H94Sfs*21 (on ENST00000370384 / NM_001251874.2; = p.H21Sfs*21 on NM_030568.5) | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- KLHDC7A | c.1669_1693del p.V559Gfs*9 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel
- METTL4 | c.1165dup p.T389Nfs*32 | Frame Shift Ins (INS) | VAF 87/176 reads (49%) | called by mutect2, pindel, varscan2
- PRAMEF15 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- QSER1 | c.1514_1515dup p.E506Kfs*33 (on ENST00000399302; = p.E635Kfs*33 on NM_001076786.3) | Frame Shift Ins (INS) | VAF 53/163 reads (33%) | called by mutect2, pindel, varscan2
- SFTPD | c.414del p.G139Efs*9 | Frame Shift Del (DEL) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- TRAV20 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AGAP3 | c.1833C>T p.C611= (on ENST00000622464; = p.C647= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/88 reads (10%) | catalogued as COSV101257296; called by muse, mutect2
- ARHGAP39 | c.696C>T p.Y232= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs1350497417, COSV52776654; called by muse, mutect2, varscan2
- BCL9 | c.735C>T p.D245= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV99325558; called by muse, mutect2, varscan2
- BPHL | c.321C>T p.R107= | Silent (SNP) | VAF 73/101 reads (72%) | catalogued as rs771151708, COSV66743974; called by muse, mutect2, varscan2
- CCDC136 | c.2796G>A p.L932= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1384342120, COSV99921925; called by muse, mutect2, varscan2
- CELSR2 | c.2418C>T p.N806= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs142987028; called by muse, mutect2, varscan2
- COL1A1 | c.3579C>T p.S1193= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV99867743; called by muse, mutect2, varscan2
- CPNE4 | c.607T>C p.L203= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs1037777107, COSV101456769; called by muse, mutect2, varscan2
- CRAT | c.1818C>T p.Y606= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100540061, COSV58875774; called by muse, mutect2, varscan2
- CSMD2 | c.2922C>T p.G974= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs371831197, COSV53939152; called by muse, mutect2, varscan2
- CSMD3 | c.9138T>G p.P3046= (on ENST00000297405 / NM_001363185.1; = p.P2877= on NM_052900.3) | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99840806; called by muse, mutect2, varscan2
- DDX19B | c.400T>C p.L134= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99054615, COSV99850075; called by muse, mutect2, varscan2
- DGKI | c.3030G>A p.V1010= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV99933449, COSV99935993; called by muse, mutect2, varscan2
- ELMO1 | c.2133G>A p.P711= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as rs377709624, COSV100163964; called by muse, mutect2
- ERVFRD-1 | c.552T>C p.T184= | Silent (SNP) | VAF 41/243 reads (17%) | catalogued as COSV100977408; called by muse, mutect2, varscan2
- FAT4 | c.642G>A p.P214= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV67902327; called by muse, mutect2, varscan2
- GPR149 | c.597T>A p.A199= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV101078580, COSV101078870; called by muse, mutect2, varscan2
- IGLV3-32 | c.279T>C p.T93= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- IMPG1 | c.579A>C p.S193= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100886518; called by muse, mutect2, varscan2
- LRP1B | c.8718T>C p.S2906= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV101258251; called by muse, mutect2
- MGAM | c.1203C>T p.R401= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs368738284; called by muse, mutect2
- NLGN1 | c.618C>T p.I206= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100849729; called by muse, mutect2, varscan2
- NLRP3 | c.162G>A p.T54= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs769297212, COSV100276389, COSV60224016; called by muse, mutect2, varscan2
- PAM | c.507G>T p.G169= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs889350253, COSV99173625; called by muse, mutect2
- PCDHA11 | c.2175G>A p.T725= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV56498950, COSV56540936; called by muse, mutect2, varscan2
- PCDHB14 | c.2130G>A p.A710= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as rs782467667, COSV53388979, COSV53391285, COSV99506260; called by muse, mutect2, varscan2
- PGAP1 | c.2244A>G p.G748= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100698292; called by muse, mutect2, varscan2
- POLA2 | c.328T>C p.L110= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as COSV99641103; called by muse, mutect2, varscan2
- RARG | c.111G>A p.P37= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs779645994, COSV100553579; called by muse, mutect2, varscan2
- RNASE12 | c.210T>C p.H70= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs779008432, COSV100250583; called by muse, mutect2, varscan2
- ROBO2 | c.2025T>G p.T675= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs1465377371, COSV100168403; called by muse, mutect2, varscan2
- RUBCNL | c.345T>G p.A115= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100529250; called by muse, mutect2, varscan2
- SLC30A8 | c.231T>C p.A77= | Silent (SNP) | VAF 39/128 reads (30%) | catalogued as COSV69977771; called by muse, mutect2, varscan2
- SLC5A12 | c.333T>G p.T111= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV99745228; called by muse, mutect2, varscan2
- SLC8A1 | c.1162A>C p.R388= | Silent (SNP) | VAF 27/148 reads (18%) | catalogued as COSV60498233; called by muse, mutect2, varscan2
- SPINK6 | c.114C>A p.V38= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100347139; called by muse, mutect2, varscan2
- SYCP1 | c.928T>C p.L310= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs773492899, COSV65701430; called by muse, mutect2, varscan2
- SYTL3 | c.1506A>G p.S502= (on ENST00000611299 / NM_001242394.1; = p.S434= on NM_001009991.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99792260; called by muse, mutect2, varscan2
- TBX2 | c.492C>G p.R164= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99539010; called by muse, mutect2, varscan2
- TRPC5 | c.1590T>G p.A530= | Silent (SNP) | VAF 41/73 reads (56%) | catalogued as rs779360220, COSV99461938; called by muse, mutect2, varscan2
- TUT4 | c.1929T>C p.D643= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs200993112, COSV99932581; called by muse, mutect2, varscan2
- VPS13A | c.7281C>T p.Y2427= | Silent (SNP) | VAF 18/134 reads (13%) | catalogued as COSV100653131; called by muse, mutect2, varscan2
- YIF1A | c.786C>T p.P262= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs769457052, COSV100268505; called by mutect2, varscan2
- CCDC28A | c.-174A>G | 5'UTR (SNP) | VAF 23/180 reads (13%) | catalogued as COSV100236565; called by muse, mutect2, varscan2
- CPLANE1 | c.*4369A>C | 3'UTR (SNP) | VAF 25/107 reads (23%) | catalogued as COSV99951142; called by muse, mutect2, varscan2
- DCAF13 | chr8:103415344 T>C | 5'Flank (SNP) | VAF 22/74 reads (30%) | catalogued as COSV52567093, COSV52567749, COSV52568626; called by muse, mutect2, varscan2
- MRC1 | c.917-150G>A | Intron (SNP) | VAF 34/222 reads (15%) | catalogued as COSV99519442; called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>G | Intron (SNP) | VAF 10/64 reads (16%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by mutect2, varscan2
- OR52A4P | n.653C>T | RNA (SNP) | VAF 122/154 reads (79%) | called by muse, mutect2, varscan2
